Somatic mutation profile of tumor specimen MP2PRT-PATCYB-TMP1-A (aliquot MP2PRT-PATCYB-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PATCYB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (952 days).
Specimen MP2PRT-PATCYB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fcdde73-1dbc-4c69-a290-cf94dea123de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCYB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCYB-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c87f5c7-538a-492b-82b5-0273fe86bb30

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4459C>T p.H1487Y | Missense Mutation (SNP) | VAF 79/516 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519207, COSV52115420, COSV52137541; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 60/462 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FUT5 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 83/775 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773420409; called by muse, mutect2, varscan2
- GAPDHS | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 109/608 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs757472989, COSV55880427; called by muse, mutect2, varscan2
- LCE2C | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 109/683 reads (16%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs199701090, COSV64228551; called by muse, mutect2, varscan2
- LONRF1 | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1400671290; called by muse, mutect2, varscan2
- PKLR | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 118/756 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as rs761210207; called by muse, mutect2, varscan2
- WWC3 | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs767870909, COSV101081924; called by muse, mutect2, varscan2
- FOXI2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 45/920 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- KIF7 | c.2961dup p.K988Efs*60 | Frame Shift Ins (INS) | VAF 75/570 reads (13%) | called by mutect2, pindel, varscan2
- SCN9A | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GREB1L | c.1332C>A p.G444= | Silent (SNP) | VAF 42/386 reads (11%) | catalogued as rs1387334234; called by muse, mutect2, varscan2
- IGF2R | c.2781G>A p.T927= | Silent (SNP) | VAF 53/447 reads (12%) | catalogued as rs1417775799; called by muse, mutect2, varscan2
- RAB3GAP2 | c.399C>T p.T133= | Silent (SNP) | VAF 8/220 reads (4%) | called by muse, mutect2
- TEK | c.2655C>A p.I885= | Silent (SNP) | VAF 45/298 reads (15%) | called by muse, mutect2, varscan2
